Gene-level copy-number profile of tumor specimen TCGA-NJ-A4YQ-01A from TCGA case TCGA-NJ-A4YQ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.6 years (25,427 days).
Specimen TCGA-NJ-A4YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.23d89731-40eb-40e2-97d0-c98c324bd365.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NJ-A4YQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/efbe313f-c87b-402f-a5e8-752419840052

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22,783; copy number 2: 30,425; copy number 3: 4,852; copy number 4: 642; copy number 5: 1,106; copy number 6: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NJ-A4YQ-01A-11D-A25M-01): tumor purity 0.29, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,110 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:205,336,061–248,919,946, 968 genes, copy number 5 (broad region; genes not listed).
- chr2:210,477,682–211,105,732, 3 genes, copy number 5 (within-gene range 4–5): CPS1, CPS1-IT1, AC012491.1.
- chr2:212,426,263–212,426,360, 1 gene, copy number 6: MIR548F2.
- chr7:81,335,106–84,528,830, 19 genes, copy number 5: AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30.
- chr7:89,443,946–90,211,635, 3 genes, copy number 6 (within-gene range 3–6): AC002383.1, RNU6-274P, STEAP2-AS1.
- chr7:106,372,251–108,130,361, 33 genes, copy number 5 (within-gene range 3–5): AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4.
- chr10:34,109,560–34,815,325, 1 gene, copy number 5 (within-gene range 4–5): PARD3.
- chr10:34,488,583–38,617,344, 82 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
